Somatic mutation profile of tumor specimen C3N-00303-01 (aliquot CPT0008800006) from CPTAC case C3N-00303, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 66.0 years (24,091 days).
Specimen C3N-00303-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c0b91d84-c802-420b-9f43-72b473998e28.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00303-31 (Blood Derived Normal), aliquot CPT0008850002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/28497433-0c59-4aa5-b3ba-62cae26d9dd5

The open-access MAF lists 34 somatic variants for this specimen: 24 protein-altering or splice-affecting, 7 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 7, Nonsense Mutation 2, Frame Shift Del 1, 5'UTR 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DIS3 | c.2339G>A p.R780K | Missense Mutation (SNP) | VAF 11/125 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66705570, COSV66707409; called by muse, mutect2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 22/384 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ATP13A5 | c.1952C>T p.T651M | Missense Mutation (SNP) | VAF 18/230 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750724708, COSV60874539; called by muse, mutect2
- BEND4 | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.005); catalogued as rs1048800530; called by muse, mutect2
- DNAH9 | c.5483C>T p.A1828V | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1428706801; called by muse, mutect2
- EPPK1 | c.6458C>T p.T2153M | Missense Mutation (SNP) | VAF 21/227 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.349); catalogued as rs201994568, COSV73262096; called by muse, mutect2
- GALNT9 | c.788G>A p.R263Q | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs782621002, COSV61100433; called by muse, mutect2
- KMT2D | c.273G>A p.W91* | Nonsense Mutation (SNP) | VAF 18/372 reads (5%) | catalogued as COSV99040311; called by muse, mutect2
- PCDHGA2 | c.2211C>G p.S737R | Missense Mutation (SNP) | VAF 33/670 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); catalogued as COSV54006316; called by muse, mutect2
- PDZD2 | c.2614G>A p.D872N | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as rs575891004, COSV56876078; called by muse, mutect2
- RBMXL3 | c.1873G>A p.G625R | Missense Mutation (SNP) | VAF 21/289 reads (7%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs782496034, COSV57751588; called by muse, mutect2
- SRGAP1 | c.1093C>T p.R365C | Missense Mutation (SNP) | VAF 20/290 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs766358165, COSV100754519; called by muse, mutect2
- TMEM44 | c.562G>A p.V188I | Missense Mutation (SNP) | VAF 16/212 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs199697463, COSV99861460; called by muse, mutect2
- VWC2L | c.542C>T p.T181M | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs767822551, COSV56975317, COSV56978390; called by muse, mutect2, varscan2
- ADAMTS18 | c.973G>T p.V325F | Missense Mutation (SNP) | VAF 12/276 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AFP | c.1794del p.K598Nfs*2 | Frame Shift Del (DEL) | VAF 15/127 reads (12%) | called by mutect2, pindel, varscan2
- DNAJC7 | c.793A>T p.K265* | Nonsense Mutation (SNP) | VAF 10/167 reads (6%) | called by muse, mutect2
- FBLN1 | c.1868C>A p.P623Q | Missense Mutation (SNP) | VAF 21/558 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.296); called by muse, mutect2
- FBXL2 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.367); called by muse, mutect2
- KRR1 | c.250A>C p.N84H | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2
- PLEKHH1 | c.793C>A p.P265T | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- SCN5A | c.4696C>A p.L1566I (on ENST00000333535 / NM_198056.3; = p.L1565I on NM_000335.5) | Missense Mutation (SNP) | VAF 11/268 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0.061); called by muse, mutect2
- SEPTIN9 | c.971G>T p.S324I (on ENST00000427177 / NM_001113491.2; = p.S306I on NM_006640.4) | Missense Mutation (SNP) | VAF 14/438 reads (3%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.775); called by muse, mutect2
- TLL1 | c.434T>C p.V145A | Missense Mutation (SNP) | VAF 25/317 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.015); called by muse, mutect2
- CEP152 | c.1179C>T p.D393= | Silent (SNP) | VAF 13/211 reads (6%) | called by muse, mutect2
- FAT4 | c.5727G>A p.Q1909= | Silent (SNP) | VAF 11/132 reads (8%) | catalogued as COSV100628462; called by muse, mutect2
- FCRL1 | c.480C>T p.T160= | Silent (SNP) | VAF 21/459 reads (5%) | called by muse, mutect2
- GALNTL6 | c.1032C>A p.I344= | Silent (SNP) | VAF 10/108 reads (9%) | catalogued as COSV72492194; called by muse, mutect2
- PCDHA8 | c.2307C>T p.L769= | Silent (SNP) | VAF 17/312 reads (5%) | catalogued as COSV65333508; called by muse, mutect2
- PIGO | c.819A>C p.V273= | Silent (SNP) | VAF 10/121 reads (8%) | called by muse, mutect2
- ZBTB37 | c.1380G>A p.G460= | Silent (SNP) | VAF 32/483 reads (7%) | catalogued as rs1339695543; called by muse, mutect2
- ANO4 | c.-87C>T | 5'UTR (SNP) | VAF 14/138 reads (10%) | catalogued as rs1394681445, COSV54593142; called by muse, mutect2
- FAM27E5 | n.345G>T | RNA (SNP) | VAF 12/326 reads (4%) | called by muse, mutect2
- PPP4R3A | c.1266+51C>G | Intron (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
